Surgical pathology report (de-identified scan), TCGA case TCGA-UN-AAZ9, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site  Boston Medical Center, specimen TCGA-UN-AAZ9-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

Date Reported:

SPECIMEN(S) RECEIVED

LEFT KIDNEY

FINAL DIAGNOSIS

LEFT KIDNEY:

Procedure: Radical Nephrectomy

Specimen laterality: Left

Tumor Site: Upper pole

Tumor Size:

Greatest dimension: 6 cm

Additional dimensions: 5 x 3 cm

Tumor Focality: Unifocal

Macroscopic Extent of Tumor: Tumor limited to kidney

Histologic Type: Papillary renal cell carcinoma

Histologic Grade (Fuhrman Nuclear Grade): G2: Nuclei slightly irregular, approximately 15 µm; nucleoli evident

Microscopic Tumor Extension: Tumor limited to kidney

Margins: Margins uninvolved by invasive carcinoma

Lymph-Vascular Invasion: Not identified

Pathologic Staging (pTNM)

Primary Tumor (pT)

pT1b: Tumor more than 4 cm but not more than 7 cm in greatest dimension, limited to the kidney

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Specify: Number examined: 0

Number positive: 0

Distant Metastasis (pM)

Not applicable

AJCC Pathologic Stage (7th Edition): (pT1b, pN0)

Pathologic Findings in Nonneoplastic Kidney:

ICD-O-3
Carcinoma, papillary renal cell 8260/3
Site: @ Kidney NOS C64.9
JN 4/30/14

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Glomerular disease (specify type): glomerular sclerosis
Tubulointerstitial disease (specify type): chronic interstitial nephritis

*** Report Electronically Signed ***

CLINICAL DIAGNOSIS AND HISTORY

Left renal mass

GROSS DESCRIPTION

The specimen is received fresh in a single container labeled with the patient's name, medical record number, and identified as "Left Kidney". The specimen consists of a left kidney weighing 286.2 grams and adjacent perirenal fat measuring 15 x 6.5 x 5.5 cm. The specimen is bivalved to show a disrupted tumor measuring approximately 6 x 5 x 3 cm with crumbling papillary pieces in the upper pole of the kidney. Note: On imaging this mass measured up to 6.7 cm in greatest cranial caudal dimension. The mass clearly disrupts the capsular surface at the upper pole. The mass is located 0.7 cm from the renal pelvis and does not appear to invade the pelvic structures. The remainder of the renal cortex is tan-brown with a well-defined cortical medullary junction. The renal cortex measures 0.6 cm in thickness and the medulla measures 1.5 cm in thickness. The pelvis and calyces are covered by smooth glistening mucosa. The adipose tissue is thinly sectioned and no lymph nodes are found. The specimen is submitted in cassettes as follows: 1 and 2- tumor and areas of necrosis, 3- tumor with capsule (3 fragments), 4 and 5- tumor with adjacent normal renal parenchyma, 6- pelvic structure margins, 7- tumor near renal parenchyma, 8 and 9- sections of unremarkable kidney parenchyma, and 10- perirenal fat. The specimen is submitted representatively in ten cassettes.

Dictated by: _____

By the signature above, the senior pathologist certifies that s/he personally conducted the evaluation of the described specimen(s) and rendered the diagnosis(es) related thereto.

Source: NCI Genomic Data Commons file ec5c51f5-c6fe-4dcd-8a90-3b64277a4a93 (TCGA-UN-AAZ9.794A5996-F823-400F-A67E-B0119DCD38B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).